CCDI case PBBPGJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/fbc7466c-8ff1-4754-82e4-6f046717f9fe

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.6 years (594 days).

Biospecimens (3 samples)
- Sample 0DDTDG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDTDV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DDTDW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
